Somatic mutation profile of tumor specimen 0DQ7VB from CCDI case PBCETK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pinealoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.1 years (5,883 days).
Specimen 0DQ7VB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 14a0bcf0-7d50-4013-ae8c-38d0c219bcd8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQ7V4 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/61a47973-a378-4c78-ae6b-ea7d0c9efeb3

The open-access MAF lists 13 somatic variants for this specimen: 11 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 1, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TTN | c.4604G>T p.R1535M (on ENST00000591111; = p.R1489M on NM_003319.4) | Missense Mutation (SNP) | VAF 17/417 reads (4%) | PolyPhen probably damaging (0.998); catalogued as COSV59976104; called by muse, mutect2
- UNC13A | c.4168A>G p.I1390V | Missense Mutation (SNP) | VAF 155/368 reads (42%) | SIFT tolerated (0.43); PolyPhen benign (0.009); catalogued as rs746832816; called by muse, mutect2, varscan2
- ZNF583 | c.1036C>A p.H346N | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52404462; called by muse, mutect2, varscan2
- ACSM2B | c.1007C>A p.A336D | Missense Mutation (SNP) | VAF 82/222 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- APC2 | c.955C>G p.Q319E | Missense Mutation (SNP) | VAF 27/155 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- CDH10 | c.73A>C p.M25L | Missense Mutation (SNP) | VAF 26/554 reads (5%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2
- CUL5 | c.781-1G>T p.X261_splice | Splice Site (SNP) | VAF 76/81 reads (94%) | called by muse, mutect2, varscan2
- EDIL3 | c.1321A>C p.T441P | Missense Mutation (SNP) | VAF 43/311 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- OBSCN | c.12667A>T p.T4223S | Missense Mutation (SNP) | VAF 12/273 reads (4%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.492); called by muse, mutect2
- SLC36A3 | c.1393T>G p.S465A | Missense Mutation (SNP) | VAF 33/218 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- SYNE1 | c.6394A>C p.K2132Q (on ENST00000367255 / NM_182961.4; = p.K2139Q on NM_033071.3) | Missense Mutation (SNP) | VAF 124/366 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- TNKS1BP1 | c.2076A>G p.P692= | Silent (SNP) | VAF 28/346 reads (8%) | called by muse, mutect2
- VPS33B | c.779-70A>G | Intron (SNP) | VAF 26/64 reads (41%) | called by muse, mutect2, varscan2
